Gene-level copy-number profile of tumor specimen TCGA-44-7667-01A from TCGA case TCGA-44-7667, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 49.5 years (18,062 days).
Specimen TCGA-44-7667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.830e3809-c72d-4e1b-a266-ad4f0ce903c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-7667-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bdaec249-bfa7-472f-96d2-3bf0f5e26574

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 492; copy number 3: 7,851; copy number 4: 14,306; copy number 5: 14,500; copy number 6: 11,745; copy number 7: 5,575; copy number 8: 1,325; copy number 9: 817; copy number 10: 696; copy number 11: 1,090; copy number 12: 754; copy number 13: 251; copy number 14: 111; copy number 15: 161; copy number 17: 64; copy number 19: 15; copy number 21: 7; copy number 23: 34; copy number 57: 14; copy number 96: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-7667-01A-31D-2062-01): tumor purity 0.37, ploidy 5.19, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,738,948–106,739,054, 1 gene: RNU6-117P.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 2,510 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:225,777,813–225,999,343, 13 genes, copy number 11: SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2.
- chr1:239,052,748–241,357,230, 32 genes, copy number 11 (within-gene range 8–11): AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1.
- chr2:38,814–61,803,388, 986 genes, copy number 11–12 (broad region; genes not listed).
- chr6:67,878,316–76,072,678, 123 genes, copy number 11–15 (within-gene range 10–15) (broad region; genes not listed).
- chr6:78,604,467–79,354,713, 13 genes, copy number 15: AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1.
- chr6:135,882,780–135,888,133, 1 gene, copy number 12 (within-gene range 9–12): AL360178.2.
- chr6:136,034,553–136,034,886, 1 gene, copy number 12: COX5BP2.
- chr8:55,696,424–78,956,082, 344 genes, copy number 11–23 (within-gene range 8–23) (broad region; genes not listed).
- chr8:91,542,924–91,907,619, 1 gene, copy number 11 (within-gene range 8–11): AC103409.1.
- chr8:91,909,738–102,561,018, 227 genes, copy number 11–17 (broad region; genes not listed).
- chr8:126,556,323–127,419,050, 1 gene, copy number 12 (within-gene range 10–12): PCAT1.
- chr8:127,072,694–145,066,685, 342 genes, copy number 12 (broad region; genes not listed).
- chr12:78,863,993–80,068,757, 17 genes, copy number 15 (within-gene range 6–15): SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P.
- chr12:80,102,899–80,103,333, 1 gene, copy number 15: AC078817.1.
- chr12:88,049,016–88,142,099, 1 gene, copy number 13 (within-gene range 9–13): CEP290.
- chr12:88,142,296–92,142,914, 54 genes, copy number 13 (within-gene range 9–13): TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1, LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1, LINC02392, LINC02822, AC084365.1, AC112481.2, AC112481.1, CCER1, LINC00615, EPYC, KERA, LUM, DCN, AC007115.1, LINC02823, AC090016.1, AC126175.1, AC126175.2, AC025254.1, AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2.
- chr14:25,124,467–42,268,586, 238 genes, copy number 11–17 (broad region; genes not listed).
- chr18:23,689,453–23,956,222, 1 gene, copy number 19 (within-gene range 9–19): LAMA3.
- chr18:23,957,754–26,657,401, 50 genes, copy number 12–19 (within-gene range 6–19): AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1.
- chr18:29,278,509–31,685,836, 25 genes, copy number 14–21 (within-gene range 3–21): AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6.
- chr18:47,285,725–49,461,347, 34 genes, copy number 14–96 (within-gene range 3–96): MIR4527HG, MIR4527, AC102797.2, AC102797.1, TPMTP1, AC026898.1, SMAD2, MTCO2P2, AC120349.3, AC120349.1, AC120349.2, ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1.
- chr20:20,017,310–20,360,703, 5 genes, copy number 11 (within-gene range 6–11): NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
